Gene-level copy-number profile of tumor specimen C3N-02145-03 from CPTAC case C3N-02145, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.4 years (24,986 days).
Specimen C3N-02145-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed6638fd-d3ab-4e2b-8f6e-f913be68f5f0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02145-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/186314d8-682f-419d-b9f8-4163a4d41e3c

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 24,835; copy number 2: 26,160; copy number 3: 6,746; copy number 4: 344; copy number 5: 27; copy number 6: 88; copy number 7: 39; copy number 8: 30; copy number 9: 1; copy number 33: 30; copy number 35: 7; copy number 39: 4.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:17,871,729–17,878,169, 2 genes (within-gene range 0–1): AC104297.1, PDCL3P3.
- chr9:17,906,563–18,910,950, 1 gene (within-gene range 0–1): ADAMTSL1.
- chr9:18,573,306–18,718,526, 3 genes (within-gene range 0–1): MIR3152, RN7SKP258, RAP1BP1.
- chr9:20,786,927–20,787,055, 1 gene (within-gene range 0–1): SNORA30B.
- chr9:21,165,637–21,441,316, 25 genes: IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1.
- chr9:21,455,484–21,456,049, 1 gene (within-gene range 0–2): IFNWP19.
- chr9:21,802,636–22,455,740, 16 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:23,894,990–23,956,444, 2 genes: AL365204.2, AL365204.3.
- chr9:39,631,046–40,153,147, 18 genes: FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:64,817,870–65,323,015, 8 genes: AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, FOXD4L5, CBWD4P.
- chr17:19,188,016–19,214,045, 4 genes: SNORD3A, SNORD3C, AC106017.1, KYNUP3.
- chr17:19,219,143–19,222,527, 1 gene (within-gene range 0–2): AC106017.2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 7,184 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,189,824–8,344,167, 7 genes, copy number 4: AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr1:9,425,094–18,956,676, 296 genes, copy number 3–4 (broad region; genes not listed).
- chr1:26,361,634–32,336,233, 203 genes, copy number 3–6 (broad region; genes not listed).
- chr1:34,166,883–42,996,814, 248 genes, copy number 3 (broad region; genes not listed).
- chr1:59,754,747–66,751,139, 107 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr5:58,198–13,944,543, 245 genes, copy number 3–8 (broad region; genes not listed).
- chr5:14,960,232–19,142,346, 82 genes, copy number 3–5 (broad region; genes not listed).
- chr5:21,750,673–22,853,344, 1 gene, copy number 3 (within-gene range 1–3): CDH12.
- chr5:22,139,247–24,644,978, 24 genes, copy number 3: AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, CDH10, AC091885.2, AC091885.1.
- chr5:25,701,217–25,911,234, 3 genes, copy number 3: RNU6-374P, AC022418.1, MSNP1.
- chr7:37,032–89,338,528, 1,534 genes, copy number 3 (broad region; genes not listed).
- chr7:97,598,933–99,394,653, 41 genes, copy number 3 (within-gene range 1–3): RN7SKP104, TAC1, ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1, NPTX2, RNU6-393P, TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1, AC004922.1, ARPC1A.
- chr7:155,181,881–156,186,223, 21 genes, copy number 3: RN7SKP280, AC099552.1, AC099552.3, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.1, RBM33, SHH, AC021218.1, Y_RNA.
- chr9:61,190,003–61,627,683, 9 genes, copy number 3: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr11:86,649–50,422,316, 1,159 genes, copy number 3 (broad region; genes not listed).
- chr11:102,107,886–102,233,424, 4 genes, copy number 3: AP001527.1, AP001527.2, YAP1, AP000942.2.
- chr11:110,577,042–112,193,805, 56 genes, copy number 3 (within-gene range 2–3): ARHGAP20, HNRNPA1P60, AP002963.1, RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN, SIK2, AP000925.1, RN7SKP273, PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1, GNG5P3, FDXACB1, C11orf1, RPL37AP8, CRYAB, HSPB2, HSPB2-C11orf52, C11orf52, DIXDC1, RNA5SP351, AP000907.1, AP000907.2, DLAT, PPIHP1, RNU6-893P, AP000907.3, PIH1D2, NKAPD1, TIMM8B, SDHD, AP002884.2, IL18, AP002884.1, TEX12.
- chr11:122,028,325–122,556,721, 1 gene, copy number 4 (within-gene range 2–4): MIR100HG.
- chr11:122,294,938–123,340,714, 31 genes, copy number 3–4: AP000755.1, AP000755.2, RNU4ATAC10P, RNU4ATAC5P, RNU6-592P, GLULP3, AP002469.1, UBASH3B, AP002762.3, AP002762.1, AP002762.2, CRTAM, JHY, RNU4-23P, ATP5PBP5, BSX, AP003040.1, RPL34P23, RPS26P43, RPL31P47, HSPA8, SNORD14E, SNORD14D, SNORD14C, AP000926.2, CLMP, AP000926.1, AP001970.1, U8, LINC02727, PHBP17.
- chr11:123,381,440–123,381,512, 1 gene, copy number 3: MIR4493.
- chr12:24,993,424–28,581,511, 83 genes, copy number 3 (broad region; genes not listed).
- chr12:68,610,855–70,920,738, 53 genes, copy number 3–5 (within-gene range 1–5): RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr12:80,936,414–82,479,239, 12 genes, copy number 3 (within-gene range 1–3): ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25.
- chr14:18,333,726–18,419,273, 4 genes, copy number 4: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:36,061,026–38,371,338, 41 genes, copy number 33–39 (within-gene range 2–39): AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1.
- chr16:11,555–34,051,363, 1,319 genes, copy number 3 (broad region; genes not listed).
- chr17:19,061,912–19,062,669, 1 gene, copy number 9: SNORD3B-1.
- chr17:37,084,992–37,406,836, 1 gene, copy number 3 (within-gene range 2–3): ACACA.
- chr17:37,375,985–42,578,366, 281 genes, copy number 3 (broad region; genes not listed).
- chr17:46,590,669–75,575,209, 793 genes, copy number 3 (broad region; genes not listed).
- chr17:77,086,716–77,217,101, 2 genes, copy number 3 (within-gene range 2–3): SNHG20, SEC14L1.
- chr17:77,152,561–83,240,804, 257 genes, copy number 3 (broad region; genes not listed).
- chr18:45,034–9,402,420, 182 genes, copy number 3 (broad region; genes not listed).
- chr18:11,981,025–14,252,140, 82 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,654. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
